Somatic mutation profile of tumor specimen C3N-02255-02 (aliquot CPT0182550006) from CPTAC case C3N-02255, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 88.9 years (32,483 days).
Specimen C3N-02255-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4852f233-f9bf-46cf-add1-6316652267c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02255-31 (Blood Derived Normal), aliquot CPT0182570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4755dde1-3bfb-4413-a332-577a34eea03b

The open-access MAF lists 83 somatic variants for this specimen: 48 protein-altering or splice-affecting, 21 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 21, Intron 8, Nonsense Mutation 4, 5'Flank 3, Frame Shift Del 2, Splice Site 2, RNA 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.3826C>G p.P1276A (on ENST00000272895 / NM_173076.3; = p.P958A on NM_015657.3) | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55967730, COSV99790257; called by muse, mutect2, varscan2
- ADGRE1 | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs778436226, COSV51672839; called by muse, mutect2, varscan2
- ALOX5 | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 140/347 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs143439556; called by muse, mutect2, varscan2
- BLK | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 124/333 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs1334454883, COSV99377114; called by muse, mutect2, varscan2
- CHRNA6 | c.216C>A p.N72K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV52380294; called by muse, mutect2, varscan2
- CILP2 | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs566930562, COSV52276653; called by muse, mutect2, varscan2
- COL4A4 | c.5029C>T p.R1677C | Missense Mutation (SNP) | VAF 246/625 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs759631057, CM074108, COSV61629349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DEPDC5 | c.2705G>A p.W902* (on ENST00000400246; = p.W971* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 136/178 reads (76%) | catalogued as rs1555900957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX36 | c.2899G>A p.V967I | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs766874499; called by muse, mutect2
- FLNC | c.5788G>A p.V1930M | Missense Mutation (SNP) | VAF 239/609 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370076553; called by muse, mutect2, varscan2
- HAL | c.855+1G>A p.X285_splice | Splice Site (SNP) | VAF 230/518 reads (44%) | catalogued as rs753129506, COSV99701387, COSV99701555; called by muse, mutect2
- LRRC8E | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 136/299 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs149212105; called by muse, mutect2, varscan2
- MAGEE1 | c.2329C>T p.R777* | Nonsense Mutation (SNP) | VAF 75/96 reads (78%) | catalogued as rs1382607216, COSV63909266; called by muse, mutect2, varscan2
- MPV17 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 177/589 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs773077701, COSV99274102; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.43084C>T p.R14362* | Nonsense Mutation (SNP) | VAF 38/76 reads (50%) | catalogued as rs199911980; called by muse, mutect2, varscan2
- NLGN4X | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 12/309 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.086); catalogued as rs1029475096, COSV52010253; called by muse, mutect2
- OR5M8 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.081); catalogued as rs371130122; called by muse, mutect2, varscan2
- PRPF40A | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775245243; called by muse, mutect2, varscan2
- PTCH1 | c.290dup p.N97Kfs*43 | Frame Shift Ins (INS) | VAF 104/144 reads (72%) | catalogued as COSV59501459; called by mutect2, varscan2
- PTEN | c.723T>G p.F241L | Missense Mutation (SNP) | VAF 97/137 reads (71%) | SIFT tolerated (0.45); PolyPhen benign (0.123); catalogued as rs17849090, CD1414194, COSV64305541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RASGRP1 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 20/52 reads (38%) | catalogued as COSV60366916; called by muse, mutect2, varscan2
- RSPO1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 214/509 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs764878797, COSV100740649, COSV62975593; called by muse, mutect2, varscan2
- SERPINB7 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs765584752, COSV60533909; called by muse, mutect2, varscan2
- SETBP1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 108/214 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as rs746316826; called by muse, mutect2, varscan2
- SHANK2 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs782236158; called by muse, mutect2, varscan2
- SLC26A5 | c.2008G>A p.V670I | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.104); catalogued as rs200013738, COSV59704592, COSV59707169; called by muse, mutect2, varscan2
- SLIT2 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.154); catalogued as rs755144502, COSV56588418; called by muse, mutect2, varscan2
- SULF2 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 152/335 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.061); catalogued as rs774487947, COSV63414509, COSV63414666; called by muse, mutect2, varscan2
- TBX3 | c.493T>C p.F165L | Missense Mutation (SNP) | VAF 157/542 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99983668; called by muse, mutect2, varscan2
- TRBV3-1 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.343); catalogued as rs959033905; called by muse, varscan2
- WSCD2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 126/435 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs371817011; called by muse, mutect2, varscan2
- ZSCAN10 | c.734C>T p.P245L (on ENST00000252463; = p.P300L on NM_032805.3) | Missense Mutation (SNP) | VAF 135/355 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs774535085, COSV52970343; called by muse, mutect2, varscan2
- ARID2 | c.1201A>G p.R401G | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- DNAH11 | c.3350A>T p.K1117I | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- FAT3 | c.7207G>A p.V2403M | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GOLGB1 | c.6608G>C p.R2203T | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JAK2 | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MRC1 | c.1802T>C p.V601A | Missense Mutation (SNP) | VAF 232/494 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MUC5B | c.2363T>C p.L788P | Missense Mutation (SNP) | VAF 171/380 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- PKN1 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 127/355 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSD3 | c.2461G>A p.G821R (on ENST00000440756; = p.G820R on NM_015310.4) | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QSOX2 | c.74C>G p.S25W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- RAB6A | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- RBM6 | c.2571_2574del p.D857Efs*3 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | called by mutect2, pindel, varscan2
- SIGLEC10 | c.774G>C p.Q258H | Missense Mutation (SNP) | VAF 114/161 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- STK26 | c.933-1G>T p.X311_splice | Splice Site (SNP) | VAF 48/54 reads (89%) | called by muse, mutect2, varscan2
- TRIM47 | c.796_797del p.R266Gfs*37 | Frame Shift Del (DEL) | VAF 78/268 reads (29%) | called by pindel, varscan2
- ZNF445 | c.2986C>T p.H996Y | Missense Mutation (SNP) | VAF 99/267 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG7 | c.1869G>A p.P623= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs779783414, COSV56295824, COSV99841520; called by muse, mutect2, varscan2
- CMKLR1 | c.984G>A p.V328= (on ENST00000312143 / NM_001142344.2; = p.V326= on NM_004072.3) | Silent (SNP) | VAF 94/287 reads (33%) | catalogued as rs138861371; called by muse, mutect2, varscan2
- DOCK6 | c.459C>T p.V153= | Silent (SNP) | VAF 207/537 reads (39%) | catalogued as rs1284542683; called by muse, mutect2, varscan2
- EPHB6 | c.252C>T p.T84= | Silent (SNP) | VAF 214/658 reads (33%) | catalogued as rs376977419; called by muse, mutect2, varscan2
- FBXL5 | c.9C>G p.P3= | Silent (SNP) | VAF 61/217 reads (28%) | called by muse, mutect2, varscan2
- GCK | c.129C>T p.R43= | Silent (SNP) | VAF 263/801 reads (33%) | catalogued as rs760912915, COSV61752581; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNQ2 | c.840C>T p.Y280= | Silent (SNP) | VAF 442/1040 reads (43%) | catalogued as rs201556105; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMA1 | c.6084C>T p.D2028= | Silent (SNP) | VAF 122/407 reads (30%) | catalogued as rs773172566, COSV101058047; called by muse, mutect2, varscan2
- MYH1 | c.2127C>T p.C709= | Silent (SNP) | VAF 101/260 reads (39%) | catalogued as rs772510610, COSV99876254; called by muse, mutect2, varscan2
- MYH7 | c.4011G>A p.R1337= | Silent (SNP) | VAF 100/118 reads (85%) | called by muse, mutect2, varscan2
- PCLO | c.14400C>T p.N4800= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs746716780, COSV61633234, COSV61639275; called by muse, mutect2, varscan2
- POLRMT | c.2289G>A p.A763= | Silent (SNP) | VAF 126/291 reads (43%) | called by muse, mutect2, varscan2
- RELN | c.9837C>T p.T3279= | Silent (SNP) | VAF 262/789 reads (33%) | catalogued as rs202224350, COSV59012090; called by muse, mutect2, varscan2
- SDK1 | c.4587G>A p.S1529= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as rs1007875661, COSV67368894; called by muse, mutect2, varscan2
- SLAMF1 | c.540G>A p.A180= | Silent (SNP) | VAF 159/720 reads (22%) | catalogued as rs370987747; called by mutect2, varscan2
- SLC25A23 | c.1368C>T p.Y456= | Silent (SNP) | VAF 228/562 reads (41%) | catalogued as rs758815574, COSV51190339; called by muse, mutect2, varscan2
- SPACA3 | c.396C>T p.Y132= | Silent (SNP) | VAF 42/109 reads (39%) | catalogued as rs146926616, COSV52190205; called by muse, mutect2, varscan2
- TRIL | c.1911C>T p.V637= | Silent (SNP) | VAF 39/306 reads (13%) | called by muse, mutect2, varscan2
- USP36 | c.817C>T p.L273= | Silent (SNP) | VAF 54/596 reads (9%) | catalogued as COSV61751823; called by muse, mutect2
- VPS41 | c.1938C>A p.I646= | Silent (SNP) | VAF 42/108 reads (39%) | called by muse, mutect2, varscan2
- ZBED9 | c.3682T>C p.L1228= | Silent (SNP) | VAF 90/163 reads (55%) | called by muse, mutect2, varscan2
- ABCC6P2 | n.296G>A | RNA (SNP) | VAF 98/238 reads (41%) | catalogued as rs1463045538; called by muse, mutect2, varscan2
- AC245047.1 | n.177C>T | RNA (SNP) | VAF 66/73 reads (90%) | catalogued as rs369195218; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1047-3050G>A | Intron (SNP) | VAF 123/422 reads (29%) | called by muse, mutect2, varscan2
- AUTS2 | c.742+9C>T | Intron (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- ENTR1 | c.220+73C>T | Intron (SNP) | VAF 267/683 reads (39%) | called by muse, mutect2, varscan2
- H2BP2 | n.1061+664A>G | Intron (SNP) | VAF 31/283 reads (11%) | called by muse, mutect2, varscan2
- KRT6A | c.1077+22G>A | Intron (SNP) | VAF 177/603 reads (29%) | catalogued as rs769203700; called by mutect2, varscan2
- RPS6KA2 | c.174+13264C>T | Intron (SNP) | VAF 91/311 reads (29%) | catalogued as rs1269391702; called by muse, mutect2, varscan2
- SIRPB2 | chr20:1491421 G>A | 5'Flank (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- SLC2A14 | chr12:7892661 G>T | 5'Flank (SNP) | VAF 60/138 reads (43%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62853892 C>G | 5'Flank (SNP) | VAF 20/34 reads (59%) | catalogued as rs758786684; called by muse, mutect2, varscan2
- ZIC4 | c.-15-1198C>A | Intron (SNP) | VAF 41/145 reads (28%) | called by muse, mutect2, varscan2
- ZNF646 | c.*1321_*1322dup | 3'UTR (INS) | VAF 38/94 reads (40%) | called by mutect2, pindel, varscan2
- ZP2 | c.484-26C>T | Intron (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2, varscan2
